Gene-level copy-number profile of tumor specimen TCGA-VQ-AA64-01A from TCGA case TCGA-VQ-AA64, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 68.7 years (25,109 days).
Specimen TCGA-VQ-AA64-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.e182cf7c-2374-479c-9237-14851ab29a64.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-AA64-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4d55fd1e-0d77-490f-97be-076fa5c9e4c2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 148; copy number 1: 18,063; copy number 2: 33,218; copy number 3: 7,509; copy number 4: 217; copy number 5: 659.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-AA64-01A-11D-A40Z-01): tumor purity 0.59, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 111 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:30,447,226–30,644,225, 1 gene (within-gene range 0–1): LCLAT1.
- chr5:59,039,761–59,063,503, 1 gene: AC092343.1.
- chr5:147,880,726–147,906,538, 1 gene (within-gene range 0–1): C5orf46.
- chr5:147,922,179–148,677,235, 17 genes: EEF1GP2, SPINK5, AC011346.1, SPINK14, SPINK6, HMGN1P16, MARCOL, SPINK13, PGBD4P3, SPINK7, SPINK9, AC091948.1, FBXO38, Metazoa_SRP, AC114939.1, HTR4, AC008627.1.
- chr6:116,254,173–116,444,861, 1 gene (within-gene range 0–1): DSE.
- chr6:116,399,395–116,463,696, 1 gene: Z84488.1.
- chr10:86,630,825–89,556,641, 88 genes (broad region; genes not listed).
- chr10:89,592,747–89,592,827, 1 gene: MIR107.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 659 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:222,088,806–248,919,946, 659 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,679. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
